Gene-level copy-number profile of tumor specimen ALCH-B02L-TTP1-A from ALCHEMIST case ALCH-B02L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.2 years (23,432 days).
Specimen ALCH-B02L-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 385e3871-b142-4ddf-a4ae-5147d658e36a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B02L-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,744 have no estimate.
https://portal.gdc.cancer.gov/files/fbcced20-2570-4ec8-a5ad-50c1e0ac083d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 384; copy number 1: 13,569; copy number 2: 26,170; copy number 3: 14,149; copy number 4: 2,636; copy number 5: 1,473; copy number 6: 340; copy number 7: 115; copy number 8: 39; copy number 14: 1; copy number 18: 3.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:1,101,260–1,225,257, 9 genes: AL031713.1, AL031598.1, AC120498.8, CACNA1H, AC120498.3, AC120498.1, AC120498.6, TPSG1, AC120498.10.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–1): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr16:33,907,419–34,163,110, 18 genes: ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:35,574,834–35,912,516, 29 genes: C1QL1P1, KIF18BP1, AC092325.1, AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr22:50,245,183–50,327,012, 7 genes: HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,971 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:90,915,298–95,247,225, 95 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:145,214,851–146,914,294, 52 genes, copy number 6: AC241585.2, AC241585.1, PPIAL4D, AC245014.2, RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1, CD160, RNF115, POLR3C, NUDT17, PIAS3, MIR6736, ANKRD35, ITGA10, AC243547.1, PEX11B, RBM8A, GNRHR2, LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV, AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1.
- chr1:148,290,889–148,519,604, 1 gene, copy number 6 (within-gene range 4–6): LINC01138.
- chr1:148,358,245–152,047,907, 178 genes, copy number 6 (broad region; genes not listed).
- chr1:244,835,616–244,971,088, 6 genes, copy number 5 (within-gene range 3–5): COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1.
- chr5:58,198–667,168, 25 genes, copy number 5 (within-gene range 4–5): AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72.
- chr5:16,615,926–16,681,905, 1 gene, copy number 5 (within-gene range 4–5): AC024588.1.
- chr5:16,661,907–16,941,951, 4 genes, copy number 5: MYO10, RNA5SP179, RPS26P28, RNU6-660P.
- chr5:26,669,346–37,753,435, 154 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:38,460,925–45,895,970, 106 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:21,528,739–21,602,383, 3 genes, copy number 5: AL512380.2, SOX4, BOLA2P3.
- chr8:7,967,344–8,024,652, 5 genes, copy number 5–6: AC130365.1, USP17L8, USP17L3, FAM90A11P, FAM90A24P.
- chr8:30,095,408–43,378,510, 257 genes, copy number 5–7 (broad region; genes not listed).
- chr8:46,922,561–60,967,775, 204 genes, copy number 5–6 (broad region; genes not listed).
- chr8:65,526,738–91,398,155, 378 genes, copy number 5–8 (broad region; genes not listed).
- chr8:93,698,561–95,156,685, 52 genes, copy number 5 (within-gene range 4–5): CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1, NDUFAF6, TP53INP1, AC087752.3, AC087752.2, AC068189.2, RNU6-1209P, MIR3150BHG, AC068189.1, MIR3150B, MIR3150A, PLEKHF2.
- chr8:97,624,203–103,073,051, 135 genes, copy number 5 (broad region; genes not listed).
- chr8:118,189,455–130,443,674, 188 genes, copy number 5 (broad region; genes not listed).
- chr8:140,505,813–141,195,808, 13 genes, copy number 5: AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr9:64,810,865–64,836,341, 2 genes, copy number 5: BNIP3P4, AL359955.1.
- chr10:11,611,305–11,612,227, 1 gene, copy number 5 (within-gene range 1–5): AL512631.2.
- chr12:30,709,552–32,756,463, 72 genes, copy number 5–8 (broad region; genes not listed).
- chr12:94,548,241–95,309,984, 18 genes, copy number 5: SUCLG2P2, MIR5700, TMCC3, MIR7844, LSM3P2, KRT19P2, MIR492, NDUFA12, NR2C1, FGD6, AC126615.2, AC126615.1, VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685.
- chr14:18,333,726–18,412,264, 2 genes, copy number 5–7: CR383658.1, CR383658.2.
- chr14:18,555,677–18,596,310, 4 genes, copy number 7: CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:18,667,249–18,712,643, 5 genes, copy number 5: CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:18,967,434–19,003,752, 3 genes, copy number 18: POTEM, AL929601.3, RNU6-1239P.
- chr14:49,643,555–49,753,150, 6 genes, copy number 5: POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1.
- chr22:18,715,815–18,719,341, 1 gene, copy number 14: PPP1R26P4.

Autosomal genes at a single copy (total copy number 1): 11,110. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
